Gene-level copy-number profile of specimen HCM-BROD-0108-C25-85E from HCMI case HCM-BROD-0108-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 66.7 years (24,349 days).
Specimen HCM-BROD-0108-C25-85E: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 10a87f8e-d63f-4938-ac2b-7c1f74e1a599.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0108-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/ebbcc66f-ca7b-45f1-a81f-c0ac5637fbd1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 583; copy number 2: 4,735; copy number 3: 24,879; copy number 4: 17,119; copy number 5: 8,652; copy number 6: 1,982; copy number 7: 216; copy number 8: 361; copy number 9: 93; copy number 10: 15; copy number 11: 13; copy number 13: 61; copy number 14: 98; copy number 24: 94.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 951 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:47,908,064–48,656,265, 16 genes, copy number 7 (within-gene range 4–7): AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP, FRMPD2, AC074325.1, RPS6P14, MAPK8, AC016397.2, ARHGAP22, ARHGAP22-IT1, AC016397.1.
- chr10:48,684,876–55,746,908, 88 genes, copy number 7–8 (broad region; genes not listed).
- chr10:62,682,652–62,805,887, 1 gene, copy number 10 (within-gene range 5–10): AC067751.1.
- chr10:62,804,720–62,808,479, 1 gene, copy number 10: ADO.
- chr10:63,167,221–64,693,446, 13 genes, copy number 11 (within-gene range 5–11): JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50.
- chr10:70,052,544–79,677,996, 220 genes, copy number 7–24 (within-gene range 2–24) (broad region; genes not listed).
- chr10:79,663,192–79,664,786, 1 gene, copy number 24 (within-gene range 2–24): AL132656.3.
- chr17:82,214,227–83,240,804, 52 genes, copy number 14: AC132872.2, SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750, AC087222.1, B3GNTL1, AC130371.1, METRNL, AC130371.2, AC144831.1, AC139099.3, AC139099.2, AC139099.1, RPL23AP87.
- chr18:8,705,661–9,254,346, 8 genes, copy number 14 (within-gene range 3–14): MTCL1, Y_RNA, AP000864.1, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1.
- chr18:13,217,498–13,652,755, 1 gene, copy number 14 (within-gene range 3–14): LDLRAD4.
- chr18:13,276,427–13,277,155, 1 gene, copy number 14: AP002505.3.
- chr18:13,362,203–14,393,909, 36 genes, copy number 14: AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A, AP001525.1, RN7SL362P, RNMT, MC5R, MC2R, AP001086.1, AC006557.6, AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2.
- chr19:35,825,372–36,418,644, 38 genes, copy number 8: NPHS1, KIRREL2, APLP1, RN7SL402P, NFKBID, AD000864.1, HCST, TYROBP, LRFN3, AF038458.3, AF038458.1, AF038458.2, SDHAF1, SYNE4, AC002116.1, ALKBH6, AC002116.2, CLIP3, THAP8, WDR62, AD000813.1, OVOL3, POLR2I, TBCB, AD001527.2, CAPNS1, AD001527.1, COX7A1, AC002984.1, ZNF565, Y_RNA, ZNF146, LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82.
- chr19:36,773,112–37,130,368, 11 genes, copy number 7–8 (within-gene range 6–8): AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3.
- chr19:37,312,837–37,488,652, 7 genes, copy number 7: ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570.
- chr19:37,545,470–37,817,300, 13 genes, copy number 7 (within-gene range 6–7): AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2.
- chr19:37,884,823–38,208,369, 3 genes, copy number 7 (within-gene range 6–7): WDR87, SIPA1L3, AC008395.1.
- chr19:38,409,051–38,636,955, 7 genes, copy number 7–8 (within-gene range 6–8): RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K.
- chr19:38,789,200–39,555,356, 53 genes, copy number 7–10: LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7, PAK4, AC011443.1, NCCRP1, SYCN, IFNL3P1, IFNL3, IFNL4, MSRB1P1, IFNL4P1, IFNL2, IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2.
- chr19:42,839,368–43,998,326, 54 genes, copy number 9–10 (within-gene range 5–10): PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8, PSG2, CEACAMP9, AC005392.1, PSG5, PSG4, CEACAMP10, PSG9, CEACAMP11, CEACAMP4, AC005392.2, CD177, AC005392.3, CD177P1, TEX101, LYPD3, PHLDB3, ETHE1, ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ, ZNF576, SRRM5, ZNF428, CADM4, PLAUR, RN7SL368P, IRGC, SMG9, KCNN4, LYPD5, AC115522.1, ZNF283, ZNF404, AC006213.6, AC006213.2, AC006213.7, AC006213.3, ZNF45, ZNF221, ZNF155, AC006213.4, AC006213.5.
- chr19:47,428,017–47,515,091, 6 genes, copy number 7: SLC8A2, AC073548.2, KPTN, NAPA-AS1, NAPA, AC073548.1.
- chr19:51,426,347–54,473,296, 255 genes, copy number 7–9 (broad region; genes not listed).
- chr19:55,132,698–55,988,629, 66 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
